TCGA case TCGA-GR-A4D9 — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes; Tissue source site: University of Nebraska Medical Center (UNMC). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5eff68ff-f6c3-40c9-9fc8-00e684a7b712

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Alive.

Diagnoses (2)
1. Diffuse large B-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Lymph nodes of head, face and neck; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 66.8 years (24,405 days); Year of diagnosis: 2009; Ann Arbor clinical stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,739 days (4.8 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Cervical lymph nodes; Sites of involvement: Lymph Node, Axillary / Lymph Node, Cervical / Lymph Node, Hilar / Lymph Node, Iliac-Common / Lymph Node, Iliac-External / Lymph Node, Inguinal / Lymph Node, Mediastinal / Lymph Node, Retroperitoneal / Lymph Node, Supraclavicular / Soft tissue / Lung, NOS / Pleura.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: Yes; Greatest tumor dimension: 7 cm; Measurement unit: Centimeters.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP-21; Days to treatment start: 22 days; Days to treatment end: 127 days; Number of cycles: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP-21; Days to treatment start: 43 days; Days to treatment end: 43 days; Number of cycles: 1.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Stem Cell Transplantation, NOS.
2. Progression of diagnosis 1 (Malignant lymphoma, non-Hodgkin, NOS), site: Connective, subcutaneous and other soft tissues, NOS. Age at diagnosis: 70.2 years (25,623 days); Days to diagnosis: 1,218 days (3.3 years); Prior treatment: Yes.

Follow-up (4 entries)
- Day 1,218 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues, NOS; Days to progression: 1,218 days (3.3 years).
- Days to follow up: 1,739 days (4.8 years); Disease response: With Tumor.
- ECOG performance status: 1.
- Follow-up contacts recording only the day: day 1,408, within 2 months after completion of first-course treatment.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive.
- CD10 (IHC): Negative.
- CD19 (Flow Cytometry): Positive.
- CD20 (IHC): Positive.
- CD23 (Flow Cytometry): Negative.
- CD5 (IHC): Negative.
- IRF4 (IHC): Positive.
- Epstein-Barr Virus (IHC): Negative.
- Lactate Dehydrogenase 420 IU [Blood test normal range upper: 618].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Immunosuppressive treatment type: Immunoglobulin; Risk factor treatment: Yes; Risk factors: Common Variable Immune Deficiency (CVID).
- Timepoint category: Initial Diagnosis; Weight: 96.8 kg; Height: 164.7 cm; BMI: 35.7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GR-A4D9-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 1 mg.
  Slide TCGA-GR-A4D9-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 3; Percent necrosis: 2; Percent stromal cells: 5; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-GR-A4D9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GR-A4D9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Treatment outcome first course: Complete Remission/Response.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: History immunological disease other: Common variable immunodeficiency.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal site involvement: 3; Tumor resected max dimension: 7.0; Bone marrow biopsy performed: Yes.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: Axillary; Lymph node involvement site: cervical; Lymph node involvement site: hilar; Lymph node involvement site: Iliac-common; Lymph node involvement site: Iliac-external; Lymph node involvement site: Inguinal; Lymph node involvement site: mediastinal; Lymph node involvement site: retroperitoneal; Lymph node involvement site: supraclavicular.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Soft Tissue (muscle  ligaments  subcutaneous); Submitted tumor site: Lung; Submitted tumor site: Pleura/Pleural Effusion.
- Tests performed: LDH level: 420.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD19.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunopheotypic analysis tested: MUM1 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunopheotypic analysis tested: BCL6 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunopheotypic analysis tested: CD23.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunopheotypic analysis tested: CD5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunopheotypic analysis tested: Eber; Immunophenotypic analysis method: Immunohistochemistry.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.
- Drug treatment 1: Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 5: Pharmaceutical therapy drug name: Intrathecal Methotrexate; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,739 days; disease-specific survival: no event (censored), 1,739 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,218 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GR-A4D9-01B-11D-A31W-01): tumor purity 0.67, ploidy 2.06, whole-genome doublings 0.
